Gene-level copy-number profile of tumor specimen TCGA-AA-3667-01A from TCGA case TCGA-AA-3667, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 36.4 years (13,302 days).
Specimen TCGA-AA-3667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6699ce92-3c1c-4d2b-9106-5f71ad55b73d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3667-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 843 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/718b8ed4-d6b2-4750-acaa-96a6dbb43a38

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 2: 5,281; copy number 3: 44; copy number 4: 43,499; copy number 6: 8,250; copy number 8: 206; copy number 9: 1,391; copy number 11: 1,080; copy number 12: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3667-01A-01D-0903-01): tumor purity 0.84, ploidy 2.23, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:20,582,892–20,641,691, 6 genes: AL163195.3, RNASE11, AL163195.2, RNASE12, AL163195.1, OR6S1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,494 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,317,017–38,329,643, 3 genes, copy number 12 (within-gene range 6–12): TRGV9, TRGVA, AC006033.2.
- chr7:142,618,849–142,802,748, 37 genes, copy number 11: TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 9 (broad region; genes not listed).
- chr20:19,693,209–20,972,562, 20 genes, copy number 12 (within-gene range 8–12): AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1.
- chr20:21,569,976–64,313,132, 1,043 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
